Somatic mutation profile of tumor specimen TARGET-40-0A4I0W-01A (aliquot TARGET-40-0A4I0W-01A-01D) from TARGET case TARGET-40-0A4I0W, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 20.1 years (7,330 days).
Specimen TARGET-40-0A4I0W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7f848e50-4cad-43a9-9d11-035b75de53bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-0A4I0W-10A (Blood Derived Normal), aliquot TARGET-40-0A4I0W-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bab92766-5ac7-411c-b3b4-7073e17446ce

The open-access MAF lists 34 somatic variants for this specimen: 22 protein-altering or splice-affecting, 7 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 7, Nonsense Mutation 4, Intron 3, RNA 1, 3'UTR 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B3GNT8 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.84); catalogued as rs367663254; called by muse, mutect2, varscan2
- BMS1 | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.124); catalogued as rs150622758; called by muse, mutect2, varscan2
- BTNL9 | c.393T>A p.Y131* | Nonsense Mutation (SNP) | VAF 26/231 reads (11%) | catalogued as rs759629533; called by muse, mutect2, varscan2
- HECTD2 | c.1144del p.I382Sfs*11 | Frame Shift Del (DEL) | VAF 21/55 reads (38%) | catalogued as rs57105282; called by mutect2, varscan2
- IGSF22 | c.1075G>T p.V359L | Missense Mutation (SNP) | VAF 34/383 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as rs1410469033, COSV60032272; called by muse, mutect2
- NCOA3 | c.4072C>G p.Q1358E (on ENST00000371998 / NM_181659.3; = p.Q1354E on NM_006534.4) | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as COSV59072422; called by muse, mutect2, varscan2
- NDUFS1 | c.1868T>G p.I623R | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs201634181; called by muse, mutect2
- PADI4 | c.254G>A p.G85D | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs910120633, COSV100966743; called by muse, mutect2
- SEMA3B | c.1825G>A p.G609R | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs1553706555; called by muse, mutect2
- TTC5 | c.1267C>T p.Q423* | Nonsense Mutation (SNP) | VAF 15/76 reads (20%) | catalogued as rs1273084243; called by muse, mutect2, varscan2
- ANKRD31 | c.1718T>G p.L573* | Nonsense Mutation (SNP) | VAF 21/112 reads (19%) | called by muse, mutect2, varscan2
- CPSF1 | c.3936G>T p.W1312C | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- DPP10 | c.844T>C p.Y282H | Missense Mutation (SNP) | VAF 52/171 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DSC3 | c.1162A>T p.N388Y | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); called by muse, mutect2
- FOXI3 | c.694G>T p.G232W | Missense Mutation (SNP) | VAF 26/230 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR179 | c.3146A>T p.D1049V (on ENST00000621958; = p.D1048V on NM_001004334.4) | Missense Mutation (SNP) | VAF 17/232 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.209); called by muse, mutect2
- RB1 | c.191dup p.L64Ffs*46 | Frame Shift Ins (INS) | VAF 10/45 reads (22%) | called by mutect2, pindel, varscan2
- RBM25 | c.1483C>T p.R495* | Nonsense Mutation (SNP) | VAF 6/110 reads (5%) | called by muse, mutect2
- SPATA31A6 | c.3456G>T p.Q1152H | Missense Mutation (SNP) | VAF 71/461 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- TRANK1 | c.7633T>A p.F2545I | Missense Mutation (SNP) | VAF 20/720 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.158); called by muse, mutect2
- TTN | c.24928G>T p.A8310S (on ENST00000591111; = p.A7383S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/257 reads (19%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF30 | c.1379A>T p.E460V | Missense Mutation (SNP) | VAF 35/331 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.079); called by muse, mutect2
- ASNS | c.75A>G p.A25= | Silent (SNP) | VAF 20/128 reads (16%) | called by muse, mutect2, varscan2
- C12orf40 | c.1674A>G p.S558= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as rs773757738; called by muse, mutect2, varscan2
- FOSL2 | c.954G>A p.L318= | Silent (SNP) | VAF 25/239 reads (10%) | called by muse, mutect2, varscan2
- KIF2B | c.1401A>G p.E467= | Silent (SNP) | VAF 16/123 reads (13%) | called by muse, mutect2, varscan2
- NANS | c.306C>T p.A102= | Silent (SNP) | VAF 37/385 reads (10%) | catalogued as rs563649207; ClinVar: likely benign; called by muse, mutect2, varscan2
- SYNE3 | c.513C>T p.D171= | Silent (SNP) | VAF 34/330 reads (10%) | catalogued as rs772987700; called by muse, mutect2
- ZNF536 | c.2832C>G p.P944= | Silent (SNP) | VAF 61/463 reads (13%) | called by muse, mutect2, varscan2
- CPLANE1 | c.*2494C>A | 3'UTR (SNP) | VAF 10/101 reads (10%) | called by muse, mutect2, varscan2
- LINC00869 | n.1015G>A | RNA (SNP) | VAF 11/50 reads (22%) | called by mutect2, varscan2
- MLST8 | c.-56+24C>T | Intron (SNP) | VAF 10/84 reads (12%) | catalogued as rs767681661; called by muse, mutect2, varscan2
- ROBO2 | c.3761-14T>C | Intron (SNP) | VAF 30/87 reads (34%) | called by muse, mutect2, varscan2
- ZNF462 | c.6832+141A>T | Intron (SNP) | VAF 14/259 reads (5%) | called by muse, mutect2
